Somatic mutation profile of tumor specimen C3L-05872-54 (aliquot CPT0299550002) from CPTAC case C3L-05872, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 29.8 years (10,885 days).
Specimen C3L-05872-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8c7592ec-d1ce-4e94-810e-53ebf5601d93.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-05872-50 (Buccal Cell Normal), aliquot CPT0299540001; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/403a8871-720e-41cf-8c28-a2eb96d66c67

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent.
By variant classification: Nonsense Mutation 1, Missense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CNTNAP2 | c.3226G>A p.A1076T | Missense Mutation (SNP) | VAF 90/249 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.908); catalogued as rs1270594834; called by muse, mutect2, varscan2
- PHF3 | c.3139C>T p.R1047* | Nonsense Mutation (SNP) | VAF 6/129 reads (5%) | catalogued as rs1340251783, COSV50328702; called by muse, mutect2
- NLRP9 | c.2688G>A p.P896= | Silent (SNP) | VAF 36/77 reads (47%) | catalogued as rs959330697; called by muse, mutect2, varscan2
